CPTAC case C3N-00665 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3d9ab180-73ab-4938-890f-cf345bfd4cf9

Demographics
Sex at birth: female; Race: white; Year of birth: 1951; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Frontal lobe; Age at diagnosis: 65.9 years (24,055 days); Year of diagnosis: 2016; Last known disease status: With tumor; Days to last known disease status: 1,585 days (4.3 years); Progression or recurrence: yes; Days to recurrence: 1,291 days (3.5 years); Days to last follow up: 1,585 days (4.3 years).
   Pathology details: Greatest tumor dimension: 5 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (5 entries)
- Days to follow up: 429 days (1.2 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 712 days (1.9 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 1,072 days (2.9 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 1,585 days (4.3 years); Disease response: With Tumor; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 1,585 days (4.3 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 1,291 days (3.5 years); Karnofsky performance status: 80; ECOG performance status: 1.

Other clinical attributes
- Weight: 58 kg; Height: 164 cm; BMI: 21.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (6 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-00665-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -5 days; Initial weight: 916 mg; Time between excision and freezing: 5 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00665-21: Section location: Frontal Lobe; Percent tumor nuclei: 60; Percent necrosis: 45.
- Sample C3N-00665-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 560 mg.
- Sample C3N-00665-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 689 mg.
- Sample C3N-00665-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 1,279 mg.
- Sample C3N-00665-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -5 days; Method of sample procurement: Blood Draw.
- Sample C3N-00665-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
